Somatic mutation profile of tumor specimen TCGA-AN-A03Y-01A (aliquot TCGA-AN-A03Y-01A-21W-A019-09) from TCGA case TCGA-AN-A03Y, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.3 years (24,232 days).
Specimen TCGA-AN-A03Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 308c1b03-8cf4-44a5-aa18-12f9e965d85b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A03Y-10A (Blood Derived Normal), aliquot TCGA-AN-A03Y-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a3fc24a-c86b-48e0-bc11-c91fcc09a317

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 12, Intron 1, Frame Shift Del 1, Splice Site 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 131/209 reads (63%) | hotspot (GDC flag); catalogued as rs587783047, CM980317, COSV55728388, COSV55734769, COSV55741582; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 97/272 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6V0D2 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 63/811 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs774964031, COSV53413041; called by muse, mutect2
- BORA | c.1514A>T p.N505I (on ENST00000613797; = p.N430I on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 254/653 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64696054; called by muse, mutect2, varscan2
- COL4A1 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 77/320 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753989899, COSV65433356; called by muse, mutect2, varscan2
- DEPDC7 | c.1118A>C p.E373A (on ENST00000241051 / NM_001077242.2; = p.E364A on NM_139160.2) | Missense Mutation (SNP) | VAF 102/201 reads (51%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.877); catalogued as COSV53809685; called by muse, mutect2, varscan2
- H1-6 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs757233893, COSV58091666; called by muse, mutect2, varscan2
- H3C8 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV59953934; called by muse, mutect2, varscan2
- HLX | c.631G>T p.V211L | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100854571; called by muse, mutect2
- KIF7 | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs780592854, COSV67999862; called by muse, mutect2, varscan2
- LGI1 | c.1123G>A p.A375T | Missense Mutation (SNP) | VAF 95/220 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs757480776, COSV65059189; called by muse, mutect2, varscan2
- LRRK1 | c.5024A>G p.N1675S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99441236; called by muse, mutect2, varscan2
- NEDD4L | c.2848C>G p.P950A (on ENST00000400345 / NM_001144967.3; = p.P930A on NM_015277.6) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV56855296; called by muse, mutect2, varscan2
- PREX2 | c.2714A>C p.K905T | Missense Mutation (SNP) | VAF 142/945 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV55766807; called by muse, mutect2, varscan2
- SLC18A3 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60335254; called by muse, mutect2, varscan2
- SLC20A2 | c.290-2A>T p.X97_splice | Splice Site (SNP) | VAF 97/1012 reads (10%) | catalogued as COSV100646129; called by muse, mutect2, varscan2
- SLC26A9 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs1444100296, COSV100536534; called by muse, mutect2
- SLC6A2 | c.273C>T p.G91= | Splice Region (SNP) | VAF 2/16 reads (13%) | catalogued as COSV54917203; called by muse, mutect2
- TMC5 | c.2405T>A p.M802K (on ENST00000396229 / NM_001105248.1; = p.M556K on NM_024780.5) | Missense Mutation (SNP) | VAF 139/358 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54911133; called by muse, mutect2, varscan2
- TPP2 | c.3099G>A p.M1033I | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.75); PolyPhen benign (0.027); catalogued as COSV65755411; called by muse, mutect2, varscan2
- TRIM26 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs747865368, COSV70983662; called by muse, mutect2, varscan2
- TRIM33 | c.2134C>A p.Q712K | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV100635516; called by muse, mutect2
- UBC | c.1849A>C p.T617P | Missense Mutation (SNP) | VAF 41/200 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV60062011; called by muse, mutect2, varscan2
- ZBED4 | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1175260621, COSV53468846; called by muse, mutect2, varscan2
- CALCR | c.1183_1184del p.L395Dfs*18 (on ENST00000649521 / NM_001164737.2; = p.L379Dfs*18 on NM_001742.4) | Frame Shift Del (DEL) | VAF 33/93 reads (35%) | called by pindel, varscan2
- ZNF586 | c.747dup p.I250Yfs*2 | Frame Shift Ins (INS) | VAF 122/346 reads (35%) | called by mutect2, pindel, varscan2
- CSPG4 | c.4992C>T p.P1664= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs368711128; called by muse, mutect2
- DIAPH2 | c.1711C>T p.L571= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV100233628; called by muse, mutect2
- GON4L | c.1362G>A p.P454= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs187289032, COSV55190954; called by muse, mutect2, varscan2
- HIF1A | c.120T>C p.L40= | Silent (SNP) | VAF 100/222 reads (45%) | catalogued as COSV60192387; called by muse, mutect2, varscan2
- IQSEC3 | c.2145C>T p.D715= (on ENST00000538872 / NM_001170738.2; = p.D412= on NM_015232.1) | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs139571026; called by muse, mutect2, varscan2
- MUC16 | c.30714G>A p.T10238= | Silent (SNP) | VAF 41/179 reads (23%) | catalogued as rs376564075; called by muse, mutect2, varscan2
- NOP9 | c.1818G>A p.L606= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV51868490; called by muse, mutect2
- PIWIL3 | c.1950C>T p.F650= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs1447409313, COSV59996461, COSV59998526; called by muse, mutect2
- PLAAT1 | c.727C>A p.R243= (on ENST00000650797; = p.R138= on NM_020386.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as COSV53232881, COSV53234504; called by muse, mutect2, varscan2
- PRAMEF6 | c.1254G>A p.E418= | Silent (SNP) | VAF 134/396 reads (34%) | called by mutect2, varscan2
- TNFRSF21 | c.606G>A p.P202= | Silent (SNP) | VAF 104/231 reads (45%) | catalogued as rs770397460, COSV57280642; called by muse, mutect2, varscan2
- WDHD1 | c.3063G>T p.G1021= | Silent (SNP) | VAF 27/121 reads (22%) | catalogued as COSV62216093; called by muse, mutect2, varscan2
- SLC25A48 | c.679+19G>A | Intron (SNP) | VAF 21/45 reads (47%) | catalogued as COSV50852297; called by muse, mutect2, varscan2
